Somatic mutation profile of tumor specimen 0DHY4F from CCDI case PBBUTJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,315 days).
Specimen 0DHY4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68510aec-c57f-49d9-b084-27e82a687037.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b30112f3-a20a-42f0-9003-db984cbbcea2

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 6, Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- MAGEB3 | c.602C>G p.T201R | Missense Mutation (SNP) | VAF 125/656 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAPK6 | c.1443A>T p.E481D | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SLIT2 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HSD17B2 | c.807C>T p.I269= | Silent (SNP) | VAF 46/714 reads (6%) | catalogued as rs374561666; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 36/526 reads (7%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- CBLB | c.2570-62T>A | Intron (SNP) | VAF 11/100 reads (11%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- MTOR | c.7165-60G>T | Intron (SNP) | VAF 66/385 reads (17%) | called by muse, mutect2, varscan2
